Gene-level copy-number profile of tumor specimen TCGA-HP-A5N0-01A from TCGA case TCGA-HP-A5N0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, clear cell type; Tissue or organ of origin: Liver; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-HP-A5N0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d5c45139-0be4-48bc-8796-71e3b7cea123.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HP-A5N0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/54ad999d-f983-43b5-ad55-052c0d19adaf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,268; copy number 2: 49,695; copy number 3: 3,259; copy number 4: 792; copy number 6: 230; copy number 7: 290; copy number 8: 268; copy number 9: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HP-A5N0-01A-11D-A28W-01): tumor purity 0.64, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 799 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:12,008,762–29,557,721, 423 genes, copy number 6–9 (within-gene range 1–9) (broad region; genes not listed).
- chr6:30,720,352–32,195,523, 164 genes, copy number 6 (broad region; genes not listed).
- chr6:42,744,498–53,100,873, 212 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,268. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
